Somatic mutation profile of tumor specimen TCGA-V1-A9OL-01A (aliquot TCGA-V1-A9OL-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14936671-bf08-4647-9d47-b3230d8f348b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OL-10A (Blood Derived Normal), aliquot TCGA-V1-A9OL-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48e4ce1e-320d-4070-b269-deab5140e39e

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1554508985, COSV52154619, COSV52189578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043625113, COSV58019828; called by muse, mutect2, varscan2
- CDK14 | c.312G>T p.K104N (on ENST00000380050 / NM_001287135.2; = p.K86N on NM_012395.3) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1188263077, COSV99726105; called by muse, mutect2, varscan2
- COL21A1 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779402; called by muse, mutect2, varscan2
- DUS1L | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs768534602, COSV57651771; called by muse, mutect2, varscan2
- EMILIN3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs778745531, COSV60035406; called by muse, mutect2
- FAM71B | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100262190; called by muse, mutect2, varscan2
- FBN3 | c.1744T>A p.C582S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99561366; called by muse, mutect2, varscan2
- FKBP4 | c.847-2A>G p.X283_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99133853; called by mutect2, varscan2
- GPC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs372530892, COSV65605013, COSV65615616; called by muse, mutect2, varscan2
- GTSF1L | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.43); catalogued as rs558143560, COSV100883940; called by muse, mutect2, varscan2
- HAUS6 | c.1545T>A p.N515K | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100997870; called by muse, mutect2
- IARS2 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228455; called by muse, mutect2, varscan2
- ITGA9 | c.2494C>G p.R832G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as COSV99291462, COSV99293311; called by muse, mutect2, varscan2
- KASH5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1323772372, COSV71358064; called by muse, mutect2
- LVRN | c.348G>T p.R116S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as COSV100773572; called by muse, mutect2, varscan2
- NCOR2 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs969895149, COSV62305747; called by muse, mutect2, varscan2
- NEU4 | c.558T>A p.C186* (on ENST00000391969 / NM_001167602.3; = p.C198* on NM_080741.4) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100372135; called by muse, mutect2, varscan2
- NR4A1 | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV99671498; called by muse, mutect2, varscan2
- OR10H5 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs746062074, COSV58278016; called by muse, mutect2, varscan2
- SPTA1 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as rs765951388, COSV63750480, COSV63754978; called by muse, mutect2, varscan2
- TNR | c.2578A>G p.I860V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV99690459; called by muse, mutect2, varscan2
- ACACA | c.4858C>G p.L1620V | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OGA | c.2690T>A p.F897Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2
- A1CF | c.63C>T p.R21= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs371584214; called by muse, mutect2, varscan2
- CNTN1 | c.621C>A p.G207= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as COSV100751639; called by muse, mutect2, varscan2
- GRAMD1A | c.1545G>A p.S515= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs746737174, COSV100526285; called by muse, mutect2, varscan2
- MYO7B | c.897C>T p.A299= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101268292; called by muse, mutect2, varscan2
- SLC22A5 | c.924G>T p.V308= | Silent (SNP) | VAF 10/237 reads (4%) | catalogued as COSV99810043; called by muse, mutect2
- SLC30A2 | c.174T>C p.G58= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100958593; called by muse, mutect2, varscan2
- TRPC5 | c.402G>T p.T134= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99461797; called by muse, mutect2
- VAT1L | c.514C>T p.L172= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100213849; called by muse, mutect2, varscan2
- ZFHX3 | c.2985C>G p.L995= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs367709501; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500378 del ATTA | 5'Flank (DEL) | VAF 6/26 reads (23%) | catalogued as rs1417886381; called by mutect2, pindel, varscan2
